Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A23R, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A23R-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-0-3

Dedifferentiated liposarcoma 8858/3
Site retroperitoneum C48.0

4/21/11 lu

....

Clinical Diagnosis & History:

Asymptomatic, CT scan for cough revealed retroperitoneal mass.

Specimens Submitted:

1: SP: Retroperitoneal tumor

DIAGNOSIS:

- 1) SOFT TISSUE; RETROPERITONEAL MASS; RESECTION:
- HIGH-GRADE DEDIFFERENTIATED LIPOSARCOMA (21.0 CM).
- MAJORITY OF TUMOR IS COMPOSED OF A HIGH-GRADE COMPONENT WITH LARGE AREAS OF NECROSIS AND HAVING A MALIGNANT FIBROUS HISTIOCYTOMA - LIKE GROWTH PATTERN.
- FOCAL LOW GRADE AREAS OF SCLEROSING LIPOSARCOMA WITH MYXOID CHANGES ARE ALSO PRESENT.
- GROSSLY TUMOR APPEARS TO BE SURROUNDED BY AN INTACT FIBROUS MEMBRANE. MICROSCOPICALLY TUMOR EXTENDS TO THE INKED SURFACE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out *** :

Gross Description:

- 1) The specimen is received fresh, labeled "Retroperitoneal tumor, stitch marks kidney capsule ". It consists of a large lobulated mass, weighing 1.5 kg and measuring 21.0 x 20. x 10 cm. A suture indicating the renal capsule margin of the kidney is present. The specimen is bisected and reveals fatty and fleshy solid areas and cystic spaces containing myxoid fluid. Approximately 60% of the tissue is necrosed with focal hemorrhage. The mass appears to be lobulated and different areas of the tumor have white glistening tissue and in some areas are more firm and have a tan color to it. Representative sections are taken from the firm and tan areas, myxoid area, the margin of the capsule to the tumor, hemorrhagic area and the necrosis. Representative sections of the specimen are submitted.

PATH
REPORT

** Continued on next page **

[page 2 of 2]
Summary of Sections:

L fatty component
LA necrosis or hemorrhage
RC renal capsule
M - mass

Summary of Sections:

Part 1: SP: Retroperitoneal tumor

Block	Sect.	Site	PCs
3		C	0
9		L	0
5		LA	0
7		M	0

PATH
REPORT

** End of Report **

Source: NCI Genomic Data Commons file a2c70fc8-8fc0-4f82-9285-c599a31bb3f2 (TCGA-DX-A23R.32946D17-C931-4DBB-9E1B-17CF2AF222EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).